Somatic mutation profile of tumor specimen TCGA-HC-7077-01A (aliquot TCGA-HC-7077-01A-11D-1961-08) from TCGA case TCGA-HC-7077, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.7 years (23,636 days).
Specimen TCGA-HC-7077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10dbefa7-b0d5-46fc-afdf-199ecba80030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7077-10A (Blood Derived Normal), aliquot TCGA-HC-7077-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/253dd9eb-7319-49df-8342-2f1a10ea3af4

The open-access MAF lists 53 somatic variants for this specimen: 44 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 7, Frame Shift Del 4, Splice Site 3, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR1 | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064796037, COSV66625753; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A4GALT | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754861621, COSV50746909; called by muse, mutect2, varscan2
- APOB | c.6034C>T p.R2012* | Nonsense Mutation (SNP) | VAF 39/162 reads (24%) | catalogued as rs147863759, CM962634; called by muse, mutect2, varscan2
- C3orf38 | c.434T>C p.F145S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59629146; called by muse, mutect2, varscan2
- CDH5 | c.1383del p.I462Lfs*42 | Frame Shift Del (DEL) | VAF 37/167 reads (22%) | catalogued as COSV58519973; called by mutect2, pindel, varscan2
- CYP19A1 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV53062971; called by muse, varscan2
- DCAF4L2 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV60476348; called by muse, mutect2, varscan2
- DHX34 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60898724; called by muse, mutect2, varscan2
- DIAPH3 | c.1357A>G p.I453V (on ENST00000400324 / NM_001042517.2; = p.I190V on NM_030932.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.881); catalogued as rs763170576, COSV57382984; called by muse, varscan2
- DNAH17 | c.13126G>A p.G4376R | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778492396, COSV53149183; called by muse, mutect2
- DPEP1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55361669; called by muse, mutect2, varscan2
- FGD5 | c.2469G>A p.M823I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs866270552, COSV53254277; called by muse, mutect2, varscan2
- GABRB2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1554102156, COSV50958383; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIP2 | c.3232G>A p.G1078S (on ENST00000619221; = p.G981S on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV56125577; called by muse, mutect2
- HECTD2 | c.1521+1G>A p.X507_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as COSV53225481; called by muse, mutect2, varscan2
- HSPG2 | c.10958T>C p.F3653S | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV65934192; called by muse, mutect2
- IGHV1-18 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 99/171 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as rs782433966; called by muse, mutect2, varscan2
- KCNQ1 | c.477+2T>C p.X159_splice | Splice Site (SNP) | VAF 36/118 reads (31%) | catalogued as COSV50136509; called by muse, mutect2, varscan2
- KCNQ2 | c.2353G>A p.D785N (on ENST00000359125 / NM_172107.4; = p.D757N on NM_004518.6) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176290657, COSV60540031; called by muse, mutect2, varscan2
- KIF21A | c.2477A>G p.K826R (on ENST00000361418 / NM_001378440.1; = p.K813R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV62778915; called by muse, mutect2, varscan2
- LARP4B | c.549G>T p.M183I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV60224444; called by muse, mutect2, varscan2
- LMTK2 | c.2485G>A p.V829I | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs763972664, COSV52005530; called by muse, mutect2, varscan2
- LRRC56 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as rs558302518, COSV54248422, COSV99530982; called by mutect2, varscan2
- LRRK2 | c.2495A>G p.Q832R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54174267; called by muse, mutect2, varscan2
- MUC16 | c.38356C>G p.Q12786E | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as COSV67500031; called by muse, mutect2, varscan2
- MZT1 | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as COSV64698404; called by muse, mutect2
- NRXN1 | c.3470G>A p.S1157N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs774423915, COSV58500077; called by muse, mutect2, varscan2
- PICK1 | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63662219; called by muse, mutect2
- PKHD1L1 | c.8131G>A p.G2711S | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as rs1201050500, COSV65739671; called by muse, mutect2, varscan2
- PNPLA1 | c.1384+2T>C p.X462_splice (on ENST00000394571 / NM_001374623.1; = p.X367_splice on NM_173676.2) | Splice Site (SNP) | VAF 54/203 reads (27%) | catalogued as rs760548516, COSV57238765; called by muse, mutect2, varscan2
- RBM22 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52273425; called by muse, mutect2, varscan2
- RPA1 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV54614103; called by muse, mutect2, varscan2
- SESN3 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1343181907, COSV53587844; called by muse, mutect2
- SHH | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as rs751492300, COSV51920610; called by muse, mutect2, varscan2
- SLC12A6 | c.379G>A p.E127K (on ENST00000354181 / NM_001365088.1; = p.E76K on NM_005135.2) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.271); catalogued as COSV51627726, COSV99271173; called by muse, mutect2, varscan2
- TRIM33 | c.3085C>T p.R1029C | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61825737; called by muse, mutect2, varscan2
- TRPM3 | c.3920G>A p.S1307N (on ENST00000357533 / NM_001366142.2; = p.S1162N on NM_020952.6) | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV62596510; called by muse, mutect2
- VWF | c.6664G>A p.G2222S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.457); catalogued as COSV54637021; called by muse, mutect2, varscan2
- WDR4 | c.439A>G p.M147V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs755199109, COSV57735975; called by muse, mutect2, varscan2
- KDF1 | c.149dup p.G51Wfs*16 | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | called by mutect2, varscan2
- LRRC41 | c.1412del p.P471Hfs*8 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel, varscan2
- SF1 | c.830_831del p.T277Sfs*16 | Frame Shift Del (DEL) | VAF 58/366 reads (16%) | called by pindel, varscan2
- SUSD6 | c.73del p.L25Ffs*3 | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | called by mutect2, pindel, varscan2
- SYNRG | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- ACCSL | c.1608C>T p.L536= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV66583076; called by muse, mutect2
- CSMD2 | c.4662G>A p.P1554= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs781311207, COSV53912122; called by muse, mutect2, varscan2
- GRIN2B | c.3456C>T p.T1152= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs752200554, COSV74206675, COSV74206895; called by muse, mutect2, varscan2
- HMCN1 | c.5427T>C p.N1809= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV54947937; called by muse, mutect2, varscan2
- KDM2B | c.2706C>T p.P902= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV65645921; called by muse, mutect2
- MCMBP | c.372G>A p.L124= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV63510867; called by muse, mutect2
- PARP9 | c.1503C>G p.T501= | Silent (SNP) | VAF 21/202 reads (10%) | catalogued as rs1407812674, COSV64452225; called by muse, mutect2, varscan2
- MAZ | c.1280-385del | Intron (DEL) | VAF 7/18 reads (39%) | catalogued as rs769505112; called by mutect2, varscan2
- RPS12 | c.336+163A>C | Intron (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100016311; called by muse, varscan2
